Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8371, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8371-01A (Primary Tumor).

[page 1 of 3]
[REDACTED] Case ID	Gross Description	Microscopic Description
[REDACTED]	Stomach segment with the tumor of 7.5 cm in its largest dimension, with the whole wall invasion; fatty tissue lymph nodes are dense, hyperemic; spleen demonstrates hyperemia.	Adenocarcinoma of the stomach, G3; with the adjacent tissue invasion, perineural invasion. Fifteen lymph nodes were examined, ten demonstrated metastases of a poorly differentiated carcinoma; spleen demonstrates anaemia of the red pulp.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:		STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Cardia Tumor size: 7.5 x 0 x 0 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 10/15 positive for metastasis (Greater and lesser omentum 10/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
	ID	Excision Date	Laterality

Source: NCI Genomic Data Commons file 6666f970-6697-47fb-a05e-a7568b0bd645 (TCGA-BR-8371.1836E793-DFAC-4FA3-BD1D-A44E2F1692A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).